Surgical pathology report (de-identified scan), TCGA case TCGA-CA-5255, project TCGA-COAD (Colon Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CA-5255-01A (Primary Tumor).

[page 1 of 3]
Pathology Form

Specimen Information

Collected by:

Date:

Preserved by:

Date:

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Colon Tumor	4.5 x 4 x 3 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3		N 0	M 0
Stage:		II	
Notes:			

[page 2 of 3]
Microscopic Description

Histological Pattern									
Cell Distribution			+ -		Structural Pattern			+ -	
Diffuse					Streaming				
Mosaic					Storiform				
Necrosis					Fibrosis				
Lymphocytic Infiltration					Palisading				
Vascular Invasion					Cystic Degeneration				
Clusterized					Bleeding				
Alveolar Formation					Myxoid Change				
Indian File					Psammoma/Calcification				

Cellular Differentiation															
Squamous		+ -		Adenomatous		+ -		Sarcomatous		+ -		Lymphomatous		+ -	
Squamoid Cell				Glandular cell				Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation:				Well	Moderate ☒	Poor
---------------------------	--	--	--	------	--	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism		☒		
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	

Nuclear Grade:				
----------------	--	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Adenocarcinoma of the colon
(moderately differentiated) Grade: II

Comments:

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			X	Streaming			
Mosaic		X		Storiform			
Necrosis		X		Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D, 35%, D2 35%, D3 35%, D4 35%, Necrosis 5%

2. Cellular Differentiation:

Well	Moderately	Poor

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis:

Adenocarcinoma, G2

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 51a6084d-715b-45bb-832d-ff067dc2e2c5 (TCGA-CA-5255.2DE28701-8490-4460-83BC-5138572FBA09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).